Somatic mutation profile of tumor specimen C3L-05815-60 (aliquot CPT0323050002) from CPTAC case C3L-05815, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 19.4 years (7,079 days).
Specimen C3L-05815-60: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66d284e1-3b82-49d5-a420-a4b03448fd35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05815-50 (Buccal Cell Normal), aliquot CPT0322970003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ab12c7e-44fc-4348-9493-c929430ad8e5

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 74/186 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs397514698, CM1412391, COSV54106047, COSV54107425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL11A1 | c.3443C>T p.P1148L | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100614473; called by muse, mutect2, varscan2
- CRYGS | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 132/318 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs764969189, COSV104411141; called by muse, mutect2, varscan2
- MAGI2 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410794318, COSV100835426, COSV62692532; called by muse, mutect2, varscan2
- SLC6A17 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 111/208 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs189456665, COSV58991953; called by muse, mutect2, varscan2
- TNRC6A | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs749539505, COSV59362081; called by muse, mutect2, varscan2
- TRIM63 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs768679845, COSV100958169; called by muse, mutect2, varscan2
- IQSEC2 | c.1813_1829delinsTGAT p.D605* (on ENST00000642864 / NM_001111125.3; = p.D400* on NM_015075.2) | Nonsense Mutation (DEL) | VAF 73/83 reads (88%) | called by pindel, varscan2*
- NRCAM | c.1018T>C p.C340R (on ENST00000379028 / NM_001371124.1; = p.C334R on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC41A2 | c.732G>C p.K244N | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZNF479 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- INSR | c.1176A>G p.S392= | Silent (SNP) | VAF 28/318 reads (9%) | called by muse, mutect2
- PAX4 | c.834C>T p.C278= | Silent (SNP) | VAF 116/246 reads (47%) | called by muse, mutect2, varscan2
- SERPINA9 | c.147C>T p.T49= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs375039631; called by muse, mutect2
- PIPSL | n.2076G>A | RNA (SNP) | VAF 163/346 reads (47%) | catalogued as rs769915638; called by muse, mutect2, varscan2
